Somatic mutation profile of tumor specimen TCGA-H2-A422-01A (aliquot TCGA-H2-A422-01A-11D-A23M-08) from TCGA case TCGA-H2-A422, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 40.3 years (14,721 days).
Specimen TCGA-H2-A422-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15a80b09-381c-483d-b7c9-599f22c28350.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-H2-A422-10A (Blood Derived Normal), aliquot TCGA-H2-A422-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/08c632b0-8902-432c-b417-4c7be70e2794

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, Intron 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CAMP | c.329G>A p.R110Q (on ENST00000296435; = p.R107Q on NM_004345.5) | Missense Mutation (SNP) | VAF 45/196 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs375338469; called by muse, mutect2, varscan2
- CECR2 | c.2023G>T p.E675* (on ENST00000342247 / NM_001290047.2; = p.E492* on NM_001290046.1) | Nonsense Mutation (SNP) | VAF 9/64 reads (14%) | catalogued as COSV99378757; called by muse, mutect2, varscan2
- CEP192 | c.3848G>C p.G1283A | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.392); catalogued as COSV100381804; called by muse, mutect2, varscan2
- FAM131B | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 54/104 reads (52%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs558108883, COSV58370182; called by muse, mutect2, varscan2
- FOLR3 | c.122A>G p.K41R | Missense Mutation (SNP) | VAF 106/281 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.222); catalogued as rs762569708, COSV61529898; called by muse, mutect2, varscan2
- KLC2 | c.1281C>G p.D427E | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs888197974, COSV100270832; called by muse, mutect2
- KLHL36 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.788); catalogued as rs1217149970, COSV99256989; called by muse, mutect2, varscan2
- PLAG1 | c.436A>G p.T146A | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs138489179; called by muse, mutect2, varscan2
- SLC5A8 | c.1368del p.G457Efs*33 | Frame Shift Del (DEL) | VAF 22/61 reads (36%) | called by mutect2, pindel, varscan2
- CACNA1C | c.1131C>T p.G377= | Silent (SNP) | VAF 63/170 reads (37%) | catalogued as rs762037748, COSV100221054; called by muse, mutect2, varscan2
- NAA60 | c.30C>T p.L10= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as COSV100692845; called by muse, mutect2, varscan2
- SLC8A1 | c.33C>T p.P11= | Silent (SNP) | VAF 36/102 reads (35%) | catalogued as rs1355392054, COSV100246758; called by muse, mutect2, varscan2
- AK9 | c.3633+13_3633+15del | Intron (DEL) | VAF 7/75 reads (9%) | catalogued as rs201441562; called by pindel, varscan2
